Gene-level copy-number profile of tumor specimen ALCH-AENW-TTP1-A from ALCHEMIST case ALCH-AENW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.6 years (23,600 days).
Specimen ALCH-AENW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 12893036-21b8-440d-a3b4-6280982d14c7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AENW-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/086e491d-1810-44d0-b553-4c5e598909fb

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 325; copy number 2: 18,596; copy number 3: 21,915; copy number 4: 10,277; copy number 5: 2,937; copy number 6: 3,192; copy number 7: 917; copy number 8: 309; copy number 9: 389; copy number 11: 17; copy number 15: 30.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:27,255,464–27,255,567, 1 gene (within-gene range 0–4): Y_RNA.
- chr2:219,054,424–219,060,921, 2 genes: IHH, MIR3131.
- chr8:7,539,628–7,601,267, 8 genes: PRR23D1, FAM90A6P, FAM90A7P, FAM90A21P, FAM90A22P, FAM90A23P, OR7E157P, AC134684.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,662 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:205,684,018–207,386,804, 56 genes, copy number 7: Metazoa_SRP, NUCKS1, SNORA72, RAB29, SLC41A1, AC119673.2, PM20D1, SLC26A9, AL713965.1, RAB7B, CTSE, BX571818.1, RHEX, AC244035.3, AVPR1B, AC244035.1, AC244035.4, RPL22P4, AC244035.2, FAM72A, SRGAP2, AC244023.1, IKBKE, MIR6769B, C1orf147, AC244034.2, RASSF5, AC244034.1, AC244034.3, EIF2D, DYRK3-AS1, DYRK3, MAPKAPK2, AL591846.1, Y_RNA, IL10, IL19, IL20, IL24, FCMR, AC098935.2, AC098935.1, PIGR, FCAMR, C1orf116, PFKFB2, YOD1, C4BPB, C4BPA, AL445493.3, AL445493.1, C4BPAP1, AL445493.2, C4BPAP2, AL596218.1, CD55.
- chr5:58,198–45,895,970, 679 genes, copy number 7–9 (broad region; genes not listed).
- chr7:36,001,317–36,148,024, 5 genes, copy number 8: AC083864.2, AC083864.1, AC083864.3, MARK2P13, AC078841.1.
- chr8:39,451,045–40,402,010, 18 genes, copy number 7: ADAM3A, AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1.
- chr11:95,482,406–135,075,908, 762 genes, copy number 7 (broad region; genes not listed).
- chr14:22,105,343–22,511,024, 65 genes, copy number 7 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 7: TRAC.
- chr14:34,485,979–36,679,362, 71 genes, copy number 8–15 (within-gene range 6–15) (broad region; genes not listed).
- chr14:37,197,913–37,596,059, 5 genes, copy number 9 (within-gene range 3–9): MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1.

Autosomal genes at a single copy (total copy number 1): 322. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
